Somatic mutation profile of tumor specimen 0DXJH3 from CCDI case PBCRKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 8.2 years (2,989 days).
Specimen 0DXJH3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47830daf-8d79-451b-8bc6-a7a5266a186a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXJEK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7f20ef2-8ff0-40ba-a765-531cd4d7e00f

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 3, Intron 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 244/1126 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 736/1059 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.4630G>A p.A1544T | Missense Mutation (SNP) | VAF 75/655 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs374544605, COSV58145274; called by muse, mutect2, varscan2
- AKNA | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 83/870 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs766859655, COSV56312207; called by muse, mutect2
- AKR1B15 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 52/1297 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1463283579; called by muse, mutect2
- GABRB3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 160/1165 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs121913125, CM021606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA1 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 214/327 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782790256; called by muse, mutect2, varscan2
- LMNTD1 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 410/1021 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs145152190, COSV51448464; called by muse, mutect2, varscan2
- OR2T33 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 499/2086 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs368660679; called by muse, varscan2
- PRX | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 218/336 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs759512054, COSV52528220; called by muse, mutect2, varscan2
- SIGLEC16 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 78/1330 reads (6%) | catalogued as rs758754534; called by muse, mutect2
- SYMPK | c.616C>A p.R206S | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV55611558; called by muse, mutect2
- ACSM5 | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 201/518 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- KPNA4 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 103/586 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- LRIF1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 147/1246 reads (12%) | called by muse, mutect2, varscan2
- NEFL | c.1621A>T p.K541* | Nonsense Mutation (SNP) | VAF 143/1267 reads (11%) | called by muse, mutect2, varscan2
- NOXRED1 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 347/801 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NTRK1 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TESMIN | c.1429A>T p.K477* | Nonsense Mutation (SNP) | VAF 349/821 reads (43%) | called by muse, mutect2, varscan2
- UBR3 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 83/797 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.123); called by muse, varscan2
- ZNF71 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 395/578 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALG10B | c.585C>T p.F195= | Silent (SNP) | VAF 155/2074 reads (7%) | called by muse, mutect2
- H3-3A | c.81C>T p.R27= | Silent (SNP) | VAF 244/1129 reads (22%) | catalogued as COSV64731906, COSV64732778; called by muse, mutect2
- NEFM | c.1749A>G p.K583= | Silent (SNP) | VAF 160/1438 reads (11%) | called by muse, mutect2, varscan2
- NLRP2 | c.45G>A p.L15= | Silent (SNP) | VAF 136/643 reads (21%) | catalogued as COSV99672592; called by muse, mutect2, varscan2
- PTPRO | c.696C>T p.I232= | Silent (SNP) | VAF 471/1274 reads (37%) | catalogued as rs764927770, COSV99840434; called by muse, mutect2, varscan2
- RASGEF1C | c.288G>A p.P96= | Silent (SNP) | VAF 290/1039 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.*7G>A | 3'UTR (SNP) | VAF 115/159 reads (72%) | catalogued as rs782146500; called by muse, mutect2, varscan2
- CGB3 | c.-10C>T | 5'UTR (SNP) | VAF 40/688 reads (6%) | catalogued as rs764152129; called by muse, mutect2
- TTN | c.10360+1893G>A | Intron (SNP) | VAF 188/462 reads (41%) | catalogued as rs145004106; ClinVar: uncertain significance; called by muse, mutect2
